Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A83P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A83P-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

Gender
Date Of Birth

DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-
- B. RIGHT PELVIC LYMPH NODES-
- C. LEFT DISTAL URETER FS-
- D. RIGHT DISTAL URETER FS-
- E. NEUROVASCULAR BUNDLE FS-
- F. BLADDER PROSTATE SEMINAL VESICLES AND DISTAL URETERS NFS-

ICD-O-3 Final
Carcinoma, urothelial NOS 8120/3
Site Bladder NOS C67.9
gn 11/24/13

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-
SIX LYMPH NODES, NEGATIVE FOR TUMOR.
- B. RIGHT PELVIC LYMPH NODES-
SIX LYMPH NODES, NEGATIVE FOR TUMOR.
- C. LEFT DISTAL URETER FS-
URETER WITH CHRONIC INFLAMMATION, NEGATIVE FOR TUMOR.
- D. RIGHT DISTAL URETER FS-
FIBROFATTY TISSUE AND URETER, NEGATIVE FOR TUMOR.
- E. NEUROVASCULAR BUNDLE FS-
CAUTERIZED AND CRUSHED ATYPICAL CELLS, CONSISTENT WITH
PERINEURAL INVASION BY CARCINOMA.
- F. BLADDER PROSTATE SEMINAL VESICLES AND DISTAL URETERS NFS-
INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: URINARY BLADDER AND PROSTATE.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: IS PRESENT. Per TSS, squamous differentiation = 5%

Prep

[page 2 of 5]
GLANDULAR DIFFERENTIATION: IS PRESENT.

TUMOR SIZE: AT LEAST 5 CM.

HISTOLOGIC GRADE: 3/3.

EXTRAVESICULAR AND EXTRAPROSTATIC MASSES: MACROSCOPICALLY PRESENT.

DIRECT INVASION OF PROSTATIC STROMA: EXTENSIVELY PRESENT.

INVASION OF SEMINAL VESICLES AND VASA: PRESENT.

SPECIMEN TYPE: RADICAL CYSTECTOMY AND PROSTATECTOMY.

ONE OF THREE PERIVESICAL LYMPH NODES IS INVOLVED BY THE TUMOR.

TNM STAGE: pT4a, pN1, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 1
NUMBER EXAMINED: 15

LYMPHATIC (SMALL VESSEL) INVASION: PRESENT.

PERINEURAL INVASION: PRESENT.

ASSOCIATED EPITHELIAL LESIONS: UROTHELIAL DYSPLASIA AND CARCINOMA IN SITU PRESENT IN URINARY BLADDER AND PROSTATE.

THE TUMOR EXTENDS TO THE MARGINS OF OF THE EXTRAVESICAL AND EXTRAPROSTATIC SOFT TISSUE.

NO TUMOR SEEN AT RESECTION MARGINS OF URETERS AND URETHRA.

Signed Others

Frozen Section

A. RIGHT AND LEFT URETERS- NO TUMOR SEEN.

NEUROVASCULAR BUNDLES- HIGHLY ATYPICAL CELLS SUSPICIOUS FOR CARCINOMA, DEFER TO PERMANENT SECTIONS.

Frozen section performed

Prep

[page 3 of 5]
Case Clinical Information
TCC OF BLADDER INVADING PROSTATE

Gross Description

- A. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" are multiple fibrofatty tissues measuring 3.5 x 3.5 x 3 cm in compact aggregate. A dominant area of induration is bisected in A1. A second area of induration is bisected in A2. Four smaller areas of induration submitted in A3.
- B. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" are pieces of fibroadipose tissue measuring 3 x 3 x 2 cm in compact aggregate. A dominant area of induration submitted in B1-B2. The remaining nodular lesions are submitted in B3.
- C. Received in formalin labeled with the patient's name and "left distal ureter-FS" is a yellow-tan tissue measuring 3 x 3 x 1 mm. The specimen is totally submitted in C1.
- D. Received in formalin labeled with the patient's name and "right distal ureter-FS" is a yellow-tan tissue measuring 4 x 1 x 0.5 mm. Totally submitted in D1.
- E. Received in formalin labeled with the patient's name and "neurovascular bundle-FS" is a yellow-tan tissue measuring 5 x 4 x 2 mm thick. Totally submitted in E1.
- F. Received in formalin labeled with the patient's name and "bladder, prostate, seminal vesicles and distal ureters-NFS" is a specimen so designated measuring 13 cm superior to inferior, 12 cm right to left and 8 cm anterior to posterior. The included prostate measures 5 cm superior to inferior, 5 cm right to left and 5.5 cm anterior to posterior. The bladder cavity is contracted measuring 2.5 cm superior to inferior, 2.5 cm right to left and 2.5 cm anterior to posterior. The bladder wall appears indurated with a conspicuous palpable indurated midline projection superiorly measuring 3 x 2 x 1.5 cm. The right and left vas deferens project along the posterior bladder wall for 4 cm on the right and 2.5 cm on the left. The right and left seminal vesicle area is effaced by pronounced induration continuous with the bladder wall. The right and left ureter stubs appear deeply retracted. Section code: F1= left vas resection margin; F2= right vas resection margin; F3= shave distal prostatic resection margin; F4-F6= mid posterior prostate; F7-F9= posterior superior prostate; F10-F13= left seminal vesicle in continuity with prostate and posterior surgical margin; F14-F17= right seminal vesicle continuous with

[page 4 of 5]
prostate and inked posterior margin; F18-F19= sections of previously described tumor projecting from superior aspect of bladder; F20= left anterior prostate; F21-F23= left lateral bladder wall extensively sampled inferior to superior; F24= right anterior superior prostate; F25-F30= right lateral bladder wall extensively sampled inferior to superior.

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
F. AA ROUTINE H&E X1 BLOCK.5
H&E X1
F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
F. AA ROUTINE H&E X1 BLOCK.7
H&E X1
F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
F. AA ROUTINE H&E X1 BLOCK.10
H&E X1

[page 5 of 5]
F. AA ROUTINE H&E X1 BLOCK.11
H&E X1
F. AA ROUTINE H&E X1 BLOCK.12
H&E X1
F. AA ROUTINE H&E X1 BLOCK.13
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1
F. AA ROUTINE H&E X1 BLOCK.16
H&E X1
F. AA ROUTINE H&E X1 BLOCK.17
H&E X1
F. AA ROUTINE H&E X1 BLOCK.18
H&E X1
F. AA ROUTINE H&E X1 BLOCK.19
H&E X1
F. AA ROUTINE H&E X1 BLOCK.20
H&E X1
F. AA ROUTINE H&E X1 BLOCK.21
H&E X1
F. AA ROUTINE H&E X1 BLOCK.22
H&E X1
F. AA ROUTINE H&E X1 BLOCK.23
H&E X1
F. AA ROUTINE H&E X1 BLOCK.24
H&E X1
F. AA ROUTINE H&E X1 BLOCK.25
H&E X1
F. AA ROUTINE H&E X1 BLOCK.26
H&E X1
F. AA ROUTINE H&E X1 BLOCK.27
H&E X1
F. AA ROUTINE H&E X1 BLOCK.28
H&E X1
F. AA ROUTINE H&E X1 BLOCK.29
H&E X1
F. AA ROUTINE H&E X1 BLOCK.30
H&E X1

Inv-A Discrepancy		
Dual/synchronous Primary Site(s)		
Case is (re-cl.):	Discontinued	Disqualified

Source: NCI Genomic Data Commons file 093407a8-dc5d-460b-8895-e26882c7312d (TCGA-K4-A83P.B5339E3F-D046-4C1F-B3B1-8E5C20D15663.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).